Gene-level copy-number profile of tumor specimen TCGA-AO-A1KP-01A from TCGA case TCGA-AO-A1KP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.3 years (28,247 days).
Specimen TCGA-AO-A1KP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a22ae2e3-fd36-4ec5-a76d-a34a3961060b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A1KP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4f312c4-9701-41bd-a2ed-34f6108af266

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,459; copy number 2: 47,206; copy number 3: 3,246; copy number 4: 920; copy number 5: 1,794; copy number 8: 54; copy number 9: 1; copy number 13: 14; copy number 15: 47; copy number 16: 5; copy number 18: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A1KP-01A-11D-A13J-01): tumor purity 0.9, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,989 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,235,475–42,207,709, 143 genes, copy number 8–18 (within-gene range 4–18) (broad region; genes not listed).
- chr8:55,067,585–59,137,502, 70 genes, copy number 5 (broad region; genes not listed).
- chr8:68,848,737–68,852,763, 1 gene, copy number 5: AC083967.1.
- chr8:72,874,859–145,066,685, 1,137 genes, copy number 5 (broad region; genes not listed).
- chr16:23,278,231–35,912,516, 586 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:46,955,362–49,275,579, 52 genes, copy number 15–16 (within-gene range 1–16): DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.3, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3, AC026470.1, MOCS1P1, N4BP1, AC026470.2, RPS2P44, AC023813.2, AC023813.1, AC007611.1, AC023813.3, AC023813.4, KLF8P1, RNU6-257P, AC023827.1, MTND4LP25, AC044798.3, AC044798.1, AC044798.2.

Autosomal genes at a single copy (total copy number 1): 6,459. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
